Somatic mutation profile of tumor specimen 0DWVGR from CCDI case PBCPPK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 2.0 years (733 days).
Specimen 0DWVGR: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b5b6706-25ac-4c90-bd4e-a6607e2b8e25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWVEQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b21feec-797e-4a33-9b32-f2071be54b43

The open-access MAF lists 32 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 7, Intron 3, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRWD1 | c.6767A>G p.E2256G | Missense Mutation (SNP) | VAF 160/353 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs1231577503; called by muse, mutect2, varscan2
- FLG | c.2639C>A p.S880Y | Missense Mutation (SNP) | VAF 81/239 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs754201216, COSV64250863; called by muse, mutect2, varscan2
- HYDIN | c.7705C>A p.L2569I | Missense Mutation (SNP) | VAF 125/282 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV59256340, COSV99991764; called by muse, mutect2, varscan2
- JHY | c.316C>A p.H106N | Missense Mutation (SNP) | VAF 101/215 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.051); catalogued as COSV56219491; called by muse, mutect2, varscan2
- OR13G1 | c.495C>A p.F165L | Missense Mutation (SNP) | VAF 168/304 reads (55%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV62944386; called by muse, mutect2, varscan2
- RPL10L | c.438G>T p.E146D | Missense Mutation (SNP) | VAF 113/248 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as COSV53558614; called by muse, mutect2, varscan2
- STK10 | c.2155C>T p.R719W | Missense Mutation (SNP) | VAF 41/469 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs764920096, COSV51570280; called by muse, mutect2
- ABCA12 | c.5975C>T p.S1992F (on ENST00000272895 / NM_173076.3; = p.S1674F on NM_015657.3) | Missense Mutation (SNP) | VAF 23/334 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- AGXT | c.328C>A p.Q110K | Missense Mutation (SNP) | VAF 153/378 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, mutect2
- CFAP54 | c.6959C>A p.A2320E | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2
- HRNR | c.7154C>A p.S2385Y | Missense Mutation (SNP) | VAF 56/495 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by mutect2, varscan2
- IQUB | c.2359C>A p.Q787K | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); called by muse, mutect2
- OR1N1 | c.747C>A p.F249L | Missense Mutation (SNP) | VAF 120/246 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- OVGP1 | c.656G>T p.W219L | Missense Mutation (SNP) | VAF 166/186 reads (89%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- RHBDL3 | c.865C>A p.L289M | Missense Mutation (SNP) | VAF 109/232 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RRH | c.184G>T p.A62S | Missense Mutation (SNP) | VAF 142/312 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- SERPINB5 | c.247T>G p.F83V | Missense Mutation (SNP) | VAF 125/281 reads (44%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- SYNE1 | c.12448G>T p.D4150Y (on ENST00000367255 / NM_182961.4; = p.D4079Y on NM_033071.3) | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2
- USP35 | c.2710G>T p.E904* | Nonsense Mutation (SNP) | VAF 18/270 reads (7%) | called by muse, mutect2
- ZBTB8B | c.448G>T p.A150S | Missense Mutation (SNP) | VAF 158/172 reads (92%) | SIFT tolerated (0.31); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ZNF599 | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.025); called by muse, mutect2
- ELP1 | c.1545G>A p.L515= | Silent (SNP) | VAF 133/296 reads (45%) | called by muse, mutect2, varscan2
- HNRNPLL | c.1275C>T p.S425= | Silent (SNP) | VAF 38/345 reads (11%) | called by muse, mutect2, varscan2
- KMT2C | c.8667C>A p.P2889= | Silent (SNP) | VAF 40/474 reads (8%) | catalogued as rs376830590; called by muse, mutect2
- OR4Q3 | c.774G>T p.L258= | Silent (SNP) | VAF 49/171 reads (29%) | catalogued as COSV59179298; called by muse, mutect2, varscan2
- PLCH1 | c.4722G>T p.L1574= (on ENST00000340059 / NM_001130960.2; = p.L1566= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 146/324 reads (45%) | called by muse, mutect2, varscan2
- RNF135 | c.1125G>T p.V375= | Silent (SNP) | VAF 185/456 reads (41%) | called by muse, mutect2, varscan2
- SCN1B | c.378G>T p.L126= | Silent (SNP) | VAF 26/408 reads (6%) | called by muse, mutect2
- ABCA9 | c.800+90C>A | Intron (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- ECRG4 | c.*7C>A | 3'UTR (SNP) | VAF 45/322 reads (14%) | called by muse, mutect2, varscan2
- MMAA | c.439+64A>T | Intron (SNP) | VAF 39/86 reads (45%) | catalogued as rs539742744, COSV55579303; called by muse, mutect2, varscan2
- NRBP1 | c.566+73C>T | Intron (SNP) | VAF 63/136 reads (46%) | called by muse, mutect2
